Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7318, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7318-01B (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PROSTATE AND BILATERAL SEMINAL VESICLES, RADICAL PROSTATECTOMY -

- A. POORLY DIFFERENTIATED PROSTATIC ADENOCARCINOMA, GLEASON SCORE 4+3=7.
- B. THE CARCINOMA INVOLVES BOTH LEFT AND RIGHT LOBES AND HAS A GREATEST NODULAR DIMENSION OF 1.9 CM IN ONE HISTOLOGIC SECTION.
- C. THE CARCINOMA INVOLVES 20% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS ESTABLISHED EXTRACAPSULAR EXTENSION IN THE REGION OF THE RIGHT POSTERIOR APEX (SLIDE V).
- E. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- F. THE CARCINOMA INVOLVES THE RIGHT POSTERIOR DISTAL URETHRAL MARGIN (SLIDE J).
- G. PERINEURAL INVASION IS IDENTIFIED.
- H. MULTIFOCAL HIGH GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA (PIN) IS SEEN.
- I. PATHOLOGIC TNM STAGE: pT3a Nx Mx.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 9.0
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	65%
WEIGHT OF PROSTATE:	48.5gm
TUMOR SIZE:	Maximum dimension: 1.9 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Established (> 0.8mm)
PERINEURAL INVASION:	Yes

ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	Focal tumor involvement at margin
RESIDUAL TUMOR:	R1
LYMPH NODES EXAMINED:	0
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pNX
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file f6aeaa71-e2df-4466-990f-8370af3e6b9b (TCGA-EJ-7318.B31F5757-0D35-4436-8F26-9AFE229049CD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).